Somatic mutation profile of tumor specimen TCGA-32-4210-01A (aliquot TCGA-32-4210-01A-01D-1353-08) from TCGA case TCGA-32-4210, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.3 years (26,768 days).
Specimen TCGA-32-4210-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4bfcf44-e579-465d-81f3-e6e915910220.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-4210-10A (Blood Derived Normal), aliquot TCGA-32-4210-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bed6e03a-d800-48d3-a1df-fb39f1c70aae

The open-access MAF lists 72 somatic variants for this specimen: 52 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 19, Splice Site 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.737T>G p.M246R | Missense Mutation (SNP) | VAF 65/80 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780074, CM157012, COSV52668375, COSV52693504, COSV52778210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.4436A>T p.E1479V | Missense Mutation (SNP) | VAF 129/352 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV57217219; called by muse, mutect2, varscan2
- AL035461.3 | c.2686G>T p.D896Y | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV66652058; called by muse, mutect2, varscan2
- ARAP2 | c.87G>C p.E29D | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV58288129; called by muse, mutect2, varscan2
- ARID3C | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 184/276 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV52407792; called by muse, mutect2, varscan2
- CAD | c.2240A>G p.K747R | Missense Mutation (SNP) | VAF 110/320 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs1190899621, COSV53028104; called by muse, mutect2, varscan2
- CALCR | c.1306C>T p.R436C (on ENST00000649521 / NM_001164737.2; = p.R420C on NM_001742.4) | Missense Mutation (SNP) | VAF 85/283 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.764); catalogued as rs567560525, COSV64009006, COSV64009049; called by muse, mutect2, varscan2
- CEP57L1 | c.848T>C p.I283T | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61245016; called by muse, varscan2
- CPVL | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs750931528, COSV55300420; called by muse, mutect2, varscan2
- CPXM1 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs1378424023, COSV66045408; called by muse, mutect2, varscan2
- CTNND2 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58897021; called by muse, mutect2, varscan2
- CYP7B1 | c.1233+1G>T p.X411_splice | Splice Site (SNP) | VAF 14/140 reads (10%) | catalogued as COSV59586344; called by muse, mutect2
- DERL2 | c.552C>A p.F184L | Missense Mutation (SNP) | VAF 100/293 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV50147503; called by muse, mutect2, varscan2
- DNAH2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as rs768754911, COSV50015282; called by muse, mutect2, varscan2
- DPP10 | c.1543T>A p.L515M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59694121; called by muse, mutect2, varscan2
- DSC2 | c.1584A>T p.K528N | Missense Mutation (SNP) | VAF 167/426 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.056); catalogued as COSV51866039; called by muse, mutect2, varscan2
- ESX1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 109/115 reads (95%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs782128803, COSV65424542; called by muse, mutect2, varscan2
- FAM71B | c.1424A>G p.N475S | Missense Mutation (SNP) | VAF 92/413 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV57228097; called by muse, mutect2, varscan2
- FAP | c.1304G>T p.S435I | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV99502160; called by muse, mutect2, varscan2
- FGD5 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs760161782, COSV53245111; called by muse, mutect2, varscan2
- GABRA6 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs761702862, COSV50883828, COSV99194556; called by muse, mutect2, varscan2
- GPC3 | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 15/400 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as COSV63665940; called by muse, mutect2
- GRM1 | c.1661A>T p.E554V | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51173055; called by muse, mutect2, varscan2
- JHY | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 163/510 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV56217679, COSV56219978; called by muse, mutect2, varscan2
- LZTR1 | c.850C>A p.R284S | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as CM154919, COSV53145634, COSV53148388; called by muse, mutect2, varscan2
- LZTS3 | c.1301G>A p.R434Q (on ENST00000329152; = p.R388Q on NM_001282533.2) | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs1332163331, COSV100232085, COSV61278145; called by muse, mutect2, varscan2
- MAP3K19 | c.1667C>T p.T556I | Missense Mutation (SNP) | VAF 139/285 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV59639700; called by muse, mutect2, varscan2
- MVP | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as rs148167046, COSV62422332; called by muse, mutect2, varscan2
- MYOM1 | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs762430543, COSV55291060; called by muse, mutect2, varscan2
- NUDT21 | c.428A>G p.D143G | Missense Mutation (SNP) | VAF 355/523 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55860144; called by muse, mutect2, varscan2
- OR5M11 | c.635T>A p.I212N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs570645003, COSV73141679, COSV73141880; called by muse, mutect2, varscan2
- OR8H3 | c.247T>A p.L83I | Missense Mutation (SNP) | VAF 276/832 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV57909580; called by muse, mutect2, varscan2
- PLEKHG1 | c.629+1G>T p.X210_splice | Splice Site (SNP) | VAF 38/236 reads (16%) | catalogued as COSV62048261; called by muse, mutect2, varscan2
- PLEKHG4B | c.409+2T>G p.X137_splice (on ENST00000283426; = p.X493_splice on NM_052909.5) | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as COSV52049220; called by muse, mutect2, varscan2
- PRSS36 | c.2162A>G p.D721G | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV51637997; called by muse, mutect2, varscan2
- PTEN | c.716T>G p.M239R | Missense Mutation (SNP) | VAF 162/183 reads (89%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as rs786204871, CM1513165, COSV64298458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM47 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55934687; called by muse, mutect2, varscan2
- ROR2 | c.1480G>A p.G494S | Missense Mutation (SNP) | VAF 409/635 reads (64%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); catalogued as rs138310082; called by muse, mutect2, varscan2
- RPGRIP1L | c.2027A>G p.N676S | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV50908742; called by muse, mutect2, varscan2
- SALL4 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.054); catalogued as rs755288586, COSV53850429; called by muse, mutect2, varscan2
- SLC28A3 | c.104A>T p.N35I | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV66153752; called by muse, mutect2, varscan2
- SMARCA5 | c.1894A>T p.I632F | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51645212; called by muse, mutect2, varscan2
- SYT16 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs201294056, COSV70856512; called by muse, mutect2, varscan2
- TMEM208 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV50762227; called by muse, mutect2, varscan2
- TMPRSS11E | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 109/404 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs552753190, COSV59519624; called by muse, mutect2, varscan2
- TRAPPC9 | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs561185313, COSV66902061; called by muse, mutect2, varscan2
- TTN | c.83101G>A p.V27701I (on ENST00000591111; = p.V20277I on NM_003319.4) | Missense Mutation (SNP) | VAF 31/64 reads (48%) | PolyPhen benign (0.001); catalogued as COSV60133134; called by muse, mutect2, varscan2
- TTN | c.41785A>T p.I13929F (on ENST00000591111; = p.I6505F on NM_003319.4) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | PolyPhen probably damaging (0.996); catalogued as COSV60133177; called by muse, mutect2, varscan2
- UBA6 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.194); catalogued as COSV59178235; called by muse, mutect2, varscan2
- ZBED2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs370143176; called by muse, mutect2, varscan2
- ZBTB34 | c.1412T>G p.V471G | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV59860054; called by muse, mutect2, varscan2
- KLHL17 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); called by muse, mutect2
- ALOX15B | c.435G>A p.R145= | Silent (SNP) | VAF 88/223 reads (39%) | catalogued as COSV66479597; called by muse, mutect2, varscan2
- BTBD11 | c.2049C>T p.G683= (on ENST00000280758 / NM_001018072.2; = p.G220= on NM_001017523.2) | Silent (SNP) | VAF 72/189 reads (38%) | catalogued as rs373750144, COSV55023936; called by muse, mutect2, varscan2
- CEACAM4 | c.18C>T p.A6= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs782500444, COSV55732051; called by muse, mutect2, varscan2
- DEPDC1 | c.1077A>G p.S359= | Silent (SNP) | VAF 85/176 reads (48%) | catalogued as COSV63958491; called by muse, mutect2, varscan2
- DIABLO | c.36C>A p.T12= (on ENST00000443649 / NM_001278303.1; = p.T85= on NM_019887.6) | Silent (SNP) | VAF 92/273 reads (34%) | catalogued as COSV57336691; called by muse, mutect2, varscan2
- FAP | c.1305C>T p.S435= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs905758769, COSV99502155; called by muse, mutect2, varscan2
- FSCB | c.777T>C p.P259= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as rs1284621897, COSV61218505; called by muse, mutect2, varscan2
- HEPACAM2 | c.1365C>T p.A455= (on ENST00000394468 / NM_001039372.4; = p.A443= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/296 reads (31%) | catalogued as COSV59061143; called by muse, mutect2, varscan2
- ITGA8 | c.939G>A p.T313= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as rs768446593, COSV65230394; called by muse, mutect2, varscan2
- LRRC56 | c.1431T>C p.R477= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV54242581; called by muse, mutect2, varscan2
- MYOM3 | c.2058C>T p.A686= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as rs1471856936, COSV58395429, COSV58395716; called by muse, mutect2, varscan2
- PCDHB1 | c.1329C>T p.S443= | Silent (SNP) | VAF 141/274 reads (51%) | catalogued as rs1304698745, COSV60629356; called by muse, mutect2, varscan2
- PTCHD3 | c.183G>A p.A61= | Silent (SNP) | VAF 125/149 reads (84%) | catalogued as rs766948492, COSV71257050; called by muse, mutect2, varscan2
- PTGER4 | c.237G>A p.T79= | Silent (SNP) | VAF 76/230 reads (33%) | catalogued as COSV56721282; called by muse, mutect2, varscan2
- PTPN13 | c.2883A>G p.E961= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs1036467840, COSV57409552; called by muse, varscan2
- SYNE1 | c.1569G>A p.L523= (on ENST00000367255 / NM_182961.4; = p.L530= on NM_033071.3) | Silent (SNP) | VAF 45/232 reads (19%) | catalogued as COSV54967295, COSV55010874; called by muse, mutect2, varscan2
- TNFSF9 | c.18C>T p.D6= | Silent (SNP) | VAF 109/151 reads (72%) | catalogued as rs1210794058, COSV55538515; called by muse, mutect2, varscan2
- TRGJ2 | c.24T>C p.F8= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- WIZ | c.4398C>T p.R1466= (on ENST00000673675 / NM_001371589.1; = p.R371= on NM_021241.3) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1415070560, COSV99653182; called by mutect2, varscan2
- MIR411 | n.93C>T | RNA (SNP) | VAF 27/76 reads (36%) | catalogued as rs752025758; called by muse, mutect2, varscan2
